Surgical pathology report (de-identified scan), TCGA case TCGA-33-AAS8, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-33-AAS8-01A (Primary Tumor).

[page 1 of 4]
=====

INTERPRETATION AND DIAGNOSIS:

1. LUNG, RIGHT UPPER LOBE, POSTERIOR SEGMENT (WEDGE RESECTION):
MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA (2.5 CM). THE
CARCINOMA EXTENDS SUBPLEURALLY AND IS ASSOCIATED WITH RETRACTION AND
SCARRING OF THE OVERLYING PLEURA. THE PARENCHYMAL LUNG MARGIN IS
NEGATIVE FOR TUMOR. SEE NOTE.

NOTE: The pathologic stage of the tumor is T1N0MX.

2. LYMPH NODES, R4 (DISSECTION): ONE (1) LYMPH NODE, NEGATIVE FOR
TUMOR.

3. LYMPH NODES, 410 (DISSECTION): ONE (1) LYMPH NODE, NEGATIVE FOR
TUMOR.

4. LYMPH NODES, STATION 7 (DISSECTION): ONE (1) LYMPH NODE, NEGATIVE
FOR TUMOR.

5. LYMPH NODE, R11 (DISSECTION): ONE (1) LYMPH NODE, NEGATIVE FOR
TUMOR.

*Electronic signature

=====

Clinical History:
LUNG CA.

GROSS DESCRIPTION

(Continued on next page.)

ICD-O.3

Carcinoma, squamous cell NOS
8670/3
Site @ Lung, upper lobe
234.1
JH 5/28/14

[page 2 of 4]
SURGICAL
PATHOLOGY

PART #1: RIGHT UPPER LOBE
Resident Pathologist:

The specimen is received fresh labeled [REDACTED] and designated right upper lobe. It consists of one grossly identifiable fragment of fleshy hemorrhagic tissue consistent with lung. A long black suture which does not designate anything in particular is attached to the specimen. The specimen weighs 66 grams and measures 10 x 6.5 x 4 cm. A palpable mass is identified in the parenchyma. The overlying pleura is inked with black ink. Serially sectioning the lung reveals a 2.5 cm tumor mass that is white tan and firm around the edges and slightly necrotic and hemorrhagic in the center. Tumor and normal lung are collected for the tumor bank and for [REDACTED] lab for further studies. A tied off vessel is grossly identified. This vessel is sampled and assumed to be a vascular margin. A long parenchymal staple margin is grossly identified in the specimen in the shape of a Y. This margin measures 9 cm at its longest aspect and there is also an arm of the staple margin that measures 4.2 cm. The tumor mass appears to grossly abut the pleura. However, the tumor mass is located approximately 1.6 cm from the closest staple margin. This staple margin is shaved and submitted in its entirety. The shave suture margin is submitted in cassettes B-D. Sections are taken of the tumor mass. Sectioning through the remainder of the lung parenchyma does not reveal any other mass lesions. Sections of normal lung are submitted. Additionally received with the specimen is a small fragment of rib. This rib measures 2.1 x 1.4 x 0.3 cm. Adherent fibrous tissue is identified on the outer aspect of the rib. Focal areas of blood clot are also identified on the outer surface of the rib. No gross abnormalities are identified. No sections are submitted. The rib is a gross diagnosis only.

SUMMARY OF SECTIONS

1 - A - 1 (POSSIBLE VASCULAR MARGIN)
3 - B-D - M EA. (SHAVE SUTURE MARGIN)
4 - E-H - 1 EA. (TUMOR)
2 - I-J - 1 EA. (NORMAL LUNG)
10 - TOTAL - M

(Continued on next page.)

[page 3 of 4]
SURGICAL
PATHOLOGY

PART #2: LYMPH NODES R4
Resident Pathologist:

The specimen is received fresh labeled [REDACTED] and designated lymph nodes R4. It consists of one tan brown yellow hemorrhagic fragment of soft tissue that measures 1 x 0.6 x 0.2 cm. The specimen is bisected. 50% of the specimen is submitted to [REDACTED] lab for further studies. The remainder of the specimen is submitted in its entirety.

SUMMARY OF SECTIONS

1 - A - 1
1 - TOTAL - 1

PART #3: LYMPH NODES R10
Resident Pathologist:

The specimen is received fresh labeled [REDACTED] and designated lymph nodes R10. It consists of one black brown fragment of soft irregular tissue that measures 1.2 x 0.4 x 0.2 cm. The specimen is bisected. 50% of the specimen is submitted to [REDACTED] lab for further studies. The remainder of the specimen is submitted in its entirety.

SUMMARY OF SECTIONS

1 - A - 1
1 - TOTAL - 1

PART #4: LYMPH NODES STATION 7
Resident Pathologist:

The specimen is received fresh labeled [REDACTED] and designated lymph nodes station 7. It consists of one brown black red yellow soft irregular tissue fragment that measures 1.6 x 0.6 x 0.2 cm. The specimen is bisected. 50% of the specimen is submitted to [REDACTED] lab. The remainder of the specimen is submitted in its entirety.

SUMMARY OF SECTIONS

(Continued on next page.)

[page 4 of 4]
SURGICAL
PATHOLOGY

1 - A - 1
1 - TOTAL - 1

PART #5: LYMPH NODE R11
Resident Pathologist:

The specimen is received fresh labeled [REDACTED] and designated lymph node R11. It consists of one black brown soft irregular tissue fragment that grossly resembles anthracotic lymph node. The specimen measures 0.9 x 0.9 x 0.1 cm. The specimen is bisected. 50% of the specimen is submitted to [REDACTED] lab for further studies. The remainder of the specimen is submitted in its entirety.

SUMMARY OF SECTIONS

1 - A - 1
1 - TOTAL - 1

Other Surgical Pathology Specimens known to the computer: [REDACTED]

(End of Report)

printed

Source: NCI Genomic Data Commons file 0c6beb87-52dd-4073-9560-66a918179c40 (TCGA-33-AAS8.637118ED-26C4-4AEF-B4C9-D06C10F98F59.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).